Somatic mutation profile of tumor specimen TARGET-10-PASWXZ-09A (aliquot TARGET-10-PASWXZ-09A-01D) from TARGET case TARGET-10-PASWXZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.6 years (2,759 days).
Specimen TARGET-10-PASWXZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91330974-c27d-477a-8b56-16760e45b483.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASWXZ-10A (Blood Derived Normal), aliquot TARGET-10-PASWXZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9baff65f-f2c3-45a3-b0cd-1040d5965f69

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Splice Site 3, Silent 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD2B | c.2486G>T p.S829I | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99478134; called by mutect2, varscan2
- CNGA2 | c.933C>A p.N311K | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61704087; called by muse, mutect2
- JAK3 | c.2659C>T p.R887C | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs759015510, COSV71685670; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, varscan2
- RGS7 | c.1082+1G>A p.X361_splice | Splice Site (SNP) | VAF 74/158 reads (47%) | catalogued as COSV58531964; called by muse, mutect2, varscan2
- STAT5B | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 102/208 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as rs1449203089, COSV53180754; called by muse, varscan2
- TAS2R41 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV101281503; called by muse, mutect2
- UBE2I | c.68G>A p.G23D | Missense Mutation (SNP) | VAF 84/138 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as COSV57646356; called by muse, mutect2, varscan2
- CENPV | c.509+1G>T p.X170_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- PARP11 | c.148-1G>T p.X50_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- PLAC8L1 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, varscan2
- RC3H1 | c.769G>T p.V257F | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC24B | c.296C>A p.T99K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); called by muse, mutect2
- SUSD4 | c.1041_1042insGGCCGCTC p.K348Gfs*25 | Frame Shift Ins (INS) | VAF 13/35 reads (37%) | called by mutect2, pindel, varscan2
- TM9SF4 | c.1471C>A p.P491T | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ECEL1 | c.321C>T p.R107= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2
- GDI1 | c.399C>T p.G133= | Silent (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- MPP3 | c.1464G>T p.L488= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- SMTN | c.51+1805C>T | Intron (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
